Gene-level copy-number profile of tumor specimen TCGA-42-2587-01A from TCGA case TCGA-42-2587, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 75.3 years (27,510 days).
Specimen TCGA-42-2587-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.978e5657-d510-4704-971e-7f5241638216.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-42-2587-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cffcd430-c588-4631-8cac-be8e3061a3b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 18,588; copy number 2: 27,185; copy number 3: 9,337; copy number 4: 3,180; copy number 5: 567; copy number 6: 572; copy number 7: 369.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-42-2587-01A-01D-1043-01): tumor purity 0.6, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,709,235–117,027,039, 7 genes: TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr8:26,835,817–27,311,272, 9 genes: COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,508 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,666,559–180,982,753, 191 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:19,471,296–21,032,845, 8 genes, copy number 7 (within-gene range 4–7): CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1.
- chr6:103,583,135–132,099,279, 398 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:68,891,276–112,963,460, 890 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr11:112,977,353–112,977,420, 1 gene, copy number 5: RNU7-187P.
- chr14:85,202,849–87,872,291, 20 genes, copy number 5: AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309, LINC01148, AL358292.1, AL352955.1, AL157688.1, LINC02296, AL135746.1, LINC02330, AL359237.1, AL136501.1.

Autosomal genes at a single copy (total copy number 1): 16,628. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
